Somatic mutation profile of tumor specimen TCGA-BR-8373-01A (aliquot TCGA-BR-8373-01A-11D-2340-08) from TCGA case TCGA-BR-8373, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, intestinal type; Tissue or organ of origin: Fundus of stomach; AJCC pathologic stage: Stage IIIA; Tumor grade: G2; Age at diagnosis: 65.0 years (23,744 days).
Specimen TCGA-BR-8373-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 80673cdf-0544-406a-b89b-a5d841b9db8f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BR-8373-10A (Blood Derived Normal), aliquot TCGA-BR-8373-10A-01D-2341-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7553a03c-f752-49ca-ab9a-5f8bf00a1fee

The open-access MAF lists 96 somatic variants for this specimen: 64 protein-altering or splice-affecting, 28 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 47, Silent 28, Nonsense Mutation 8, Frame Shift Del 5, Intron 2, Frame Shift Ins 1, In Frame Ins 1, 3'UTR 1, RNA 1, Splice Region 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABAT | c.539G>A p.R180Q | Missense Mutation (SNP) | VAF 25/50 reads (50%) | SIFT tolerated (0.56); PolyPhen benign (0.066); catalogued as rs776431473, COSV51620565; called by muse, mutect2, varscan2
- AC008397.2 | c.976G>T p.D326Y | Missense Mutation (SNP) | VAF 26/91 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.889); catalogued as COSV53206454; called by muse, mutect2, varscan2
- ADAMTS13 | c.3280C>T p.R1094C | Missense Mutation (SNP) | VAF 37/173 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.939); catalogued as rs781965782, COSV52469634; called by muse, mutect2, varscan2
- ADAMTS16 | c.1975C>T p.R659* | Nonsense Mutation (SNP) | VAF 47/108 reads (44%) | catalogued as rs756783420, COSV56976962; called by muse, mutect2, varscan2
- ALOX5AP | c.467C>T p.P156L | Missense Mutation (SNP) | VAF 49/121 reads (40%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.262); catalogued as COSV66857886; called by muse, mutect2, varscan2
- ANK2 | c.2545G>T p.E849* | Nonsense Mutation (SNP) | VAF 4/42 reads (10%) | catalogued as COSV52157315; called by muse, mutect2
- ASB5 | c.215C>T p.S72L | Missense Mutation (SNP) | VAF 38/61 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1187944568, COSV56670047; called by muse, mutect2, varscan2
- BRD4 | c.3139C>T p.R1047W | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.853); catalogued as rs1373343624, COSV54585291; called by muse, mutect2, varscan2
- BTNL3 | c.1009del p.Q337Kfs*15 | Frame Shift Del (DEL) | VAF 21/77 reads (27%) | catalogued as COSV61565878; called by mutect2, pindel, varscan2
- CD33 | c.925-2A>C p.X309_splice | Splice Site (SNP) | VAF 6/37 reads (16%) | catalogued as COSV51801109, COSV51805320; called by muse, mutect2, varscan2
- CDC25A | c.339G>C p.L113F | Missense Mutation (SNP) | VAF 22/65 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV56770432; called by muse, mutect2, varscan2
- DCST2 | c.946C>A p.L316M | Missense Mutation (SNP) | VAF 19/51 reads (37%) | SIFT tolerated (0.13); PolyPhen benign (0.034); catalogued as COSV55051251; called by muse, mutect2, varscan2
- DNAH5 | c.12827T>C p.M4276T | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.101); catalogued as rs749125278, COSV54219524; called by muse, mutect2, varscan2
- FASTKD5 | c.62C>T p.A21V | Missense Mutation (SNP) | VAF 40/108 reads (37%) | SIFT tolerated (0.16); PolyPhen benign (0.007); catalogued as COSV53905599; called by muse, mutect2, varscan2
- FBP1 | c.708T>G p.D236E | Missense Mutation (SNP) | VAF 3/23 reads (13%) | SIFT tolerated (0.46); PolyPhen benign (0.007); catalogued as COSV64689224; called by muse, mutect2
- FGD5 | c.1120T>G p.S374A | Missense Mutation (SNP) | VAF 12/88 reads (14%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.003); catalogued as COSV53241394; called by muse, mutect2, varscan2
- GBGT1 | c.460G>A p.V154I | Missense Mutation (SNP) | VAF 19/41 reads (46%) | SIFT tolerated (0.66); PolyPhen benign (0.001); catalogued as rs769944218, COSV64410111; called by muse, mutect2, varscan2
- GSE1 | c.2138G>A p.R713Q | Missense Mutation (SNP) | VAF 3/14 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0.06); catalogued as rs1339384920, COSV53671450; called by muse, mutect2
- HEATR5B | c.992T>G p.L331R | Missense Mutation (SNP) | VAF 35/119 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs1327078783, COSV51852041; called by muse, mutect2, varscan2
- HRNR | c.5500C>T p.R1834* | Nonsense Mutation (SNP) | VAF 55/716 reads (8%) | catalogued as rs755669550, COSV100913476; called by muse, mutect2, varscan2
- HSPA2 | c.1859G>A p.G620D | Missense Mutation (SNP) | VAF 18/27 reads (67%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.011); catalogued as COSV55969393; called by muse, mutect2, varscan2
- ICA1L | c.758A>C p.H253P | Missense Mutation (SNP) | VAF 10/65 reads (15%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as COSV64173180; called by muse, mutect2, varscan2
- IFI30 | c.202T>A p.Y68N | Missense Mutation (SNP) | VAF 6/74 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55847687; called by muse, mutect2
- IFT122 | c.2497G>A p.D833N (on ENST00000348417 / NM_052989.3; = p.D774N on NM_018262.4) | Missense Mutation (SNP) | VAF 34/88 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); catalogued as COSV56202327; called by muse, mutect2, varscan2
- IGHM | c.1172G>A p.R391Q | Missense Mutation (SNP) | VAF 20/30 reads (67%) | SIFT tolerated (0.27); PolyPhen benign (0.412); catalogued as rs372720307; called by muse, mutect2, varscan2
- IGSF11 | c.1049G>A p.G350D (on ENST00000393775 / NM_001015887.3; = p.G349D on NM_152538.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 60/167 reads (36%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.723); catalogued as rs1328317547, COSV61165898; called by muse, mutect2, varscan2
- KCNK18 | c.659G>A p.R220H | Missense Mutation (SNP) | VAF 16/91 reads (18%) | SIFT tolerated (0.11); PolyPhen benign (0.034); catalogued as rs377258890; called by muse, mutect2, varscan2
- KIF3C | c.1480G>C p.E494Q | Missense Mutation (SNP) | VAF 8/61 reads (13%) | SIFT tolerated (0.18); PolyPhen benign (0.057); catalogued as rs775740030, COSV53098921; called by muse, mutect2, varscan2
- LHFPL3 | c.631G>T p.E211* | Nonsense Mutation (SNP) | VAF 3/11 reads (27%) | catalogued as COSV67810058; called by muse, mutect2
- MSR1 | c.704A>G p.H235R | Missense Mutation (SNP) | VAF 9/15 reads (60%) | SIFT tolerated (0.19); PolyPhen benign (0.157); catalogued as rs965611078, COSV50510053; called by muse, mutect2, varscan2
- MYO3A | c.3145A>C p.N1049H | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV56327897; called by muse, mutect2, varscan2
- NAA60 | c.683C>T p.S228L | Missense Mutation (SNP) | VAF 3/9 reads (33%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.837); catalogued as rs1365101804, COSV62654640; called by muse, mutect2
- OPRD1 | c.263T>C p.I88T | Missense Mutation (SNP) | VAF 24/112 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as COSV52381685; called by muse, mutect2, varscan2
- OR2A25 | c.696del p.C233Afs*55 | Frame Shift Del (DEL) | VAF 41/125 reads (33%) | catalogued as COSV101376403; called by mutect2, pindel, varscan2
- OR56B1 | c.929C>T p.A310V | Missense Mutation (SNP) | VAF 89/198 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.066); catalogued as COSV57722780; called by muse, mutect2, varscan2
- OR8J1 | c.604T>C p.S202P | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.936); catalogued as COSV57317851; called by muse, mutect2, varscan2
- PCDHB4 | c.679G>A p.V227I | Missense Mutation (SNP) | VAF 23/79 reads (29%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.116); catalogued as rs782751722, COSV52021780; called by muse, mutect2, varscan2
- PCDHGA4 | c.1420A>G p.M474V | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.001); catalogued as COSV53933182; called by muse, varscan2
- PHACTR2 | c.421G>A p.E141K | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.985); catalogued as COSV59853844; called by muse, mutect2
- PTPRT | c.4191G>A p.M1397I | Missense Mutation (SNP) | VAF 24/119 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV61967372; called by muse, mutect2, varscan2
- RAB36 | c.865G>A p.E289K | Missense Mutation (SNP) | VAF 20/70 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.577); catalogued as rs145390018; called by muse, mutect2, varscan2
- RGS12 | c.3574G>T p.E1192* | Nonsense Mutation (SNP) | VAF 19/72 reads (26%) | catalogued as rs764580511, COSV58751011, COSV58754158; called by muse, mutect2, varscan2
- RTP1 | c.539G>A p.R180H | Missense Mutation (SNP) | VAF 19/54 reads (35%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.997); catalogued as COSV56617942, COSV56618257; called by muse, mutect2, varscan2
- SCGN | c.431C>T p.A144V | Missense Mutation (SNP) | VAF 34/211 reads (16%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as COSV58545248; called by muse, mutect2, varscan2
- SCN9A | c.2504G>A p.R835Q (on ENST00000303354; = p.R824Q on NM_002977.3) | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs375375336; called by muse, mutect2, varscan2
- SHMT2 | c.1438C>T p.Q480* | Nonsense Mutation (SNP) | VAF 56/159 reads (35%) | catalogued as COSV61073763; called by muse, mutect2, varscan2
- SLC18A3 | c.1127C>T p.A376V | Missense Mutation (SNP) | VAF 25/67 reads (37%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.783); catalogued as COSV60323856; called by muse, mutect2, varscan2
- SPAG1 | c.1837C>G p.R613G | Missense Mutation (SNP) | VAF 20/51 reads (39%) | SIFT tolerated (0.19); PolyPhen benign (0.017); catalogued as COSV104381775, COSV52559401; called by muse, mutect2, varscan2
- SYNGR2 | c.305A>T p.K102M | Missense Mutation (SNP) | VAF 13/63 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56745586; called by muse, mutect2, varscan2
- TAS1R1 | c.353T>C p.V118A | Missense Mutation (SNP) | VAF 35/173 reads (20%) | SIFT tolerated (0.54); PolyPhen benign (0.022); catalogued as COSV60227782; called by muse, mutect2, varscan2
- TAS2R1 | c.868A>T p.K290* | Nonsense Mutation (SNP) | VAF 21/118 reads (18%) | catalogued as COSV66778069, COSV66778422; called by muse, mutect2, varscan2
- TIAM2 | c.2927A>G p.D976G | Missense Mutation (SNP) | VAF 13/132 reads (10%) | SIFT tolerated (0.4); PolyPhen benign (0.001); catalogued as COSV59693064; called by muse, mutect2, varscan2
- TJP2 | c.1028A>G p.N343S | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT tolerated (0.29); PolyPhen benign (0.264); catalogued as rs763855572, COSV55265839, COSV55265872; called by muse, mutect2, varscan2
- TMEM258 | c.111C>T p.F37= | Splice Region (SNP) | VAF 4/18 reads (22%) | catalogued as rs1565314026, COSV53885663; called by muse, mutect2
- UBA7 | c.1766C>T p.A589V | Missense Mutation (SNP) | VAF 9/102 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.059); catalogued as rs1265395397, COSV61092068; called by muse, mutect2
- WDR26 | c.1217G>A p.R406Q (on ENST00000414423 / NM_001379403.1; = p.R306Q on NM_025160.7) | Missense Mutation (SNP) | VAF 33/77 reads (43%) | SIFT tolerated (0.24); PolyPhen benign (0.006); catalogued as rs565415424, COSV54354864; called by muse, mutect2, varscan2
- ZNF560 | c.1723A>C p.M575L | Missense Mutation (SNP) | VAF 71/111 reads (64%) | SIFT tolerated (0.35); PolyPhen benign (0.007); catalogued as COSV56867388; called by muse, mutect2, varscan2
- ADH6 | c.863_865dup p.G288dup | In Frame Ins (INS) | VAF 10/54 reads (19%) | called by mutect2, pindel, varscan2
- AGO4 | c.852dup p.P285Sfs*19 | Frame Shift Ins (INS) | VAF 12/48 reads (25%) | called by mutect2, pindel, varscan2
- PRRC2A | c.4484del p.G1495Vfs*46 | Frame Shift Del (DEL) | VAF 8/55 reads (15%) | called by mutect2, pindel, varscan2
- RPS27A | c.62A>T p.D21V | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.609); called by muse, mutect2
- SLCO2B1 | c.706_721del p.M236Pfs*25 | Frame Shift Del (DEL) | VAF 8/108 reads (7%) | called by mutect2, pindel
- SYCP1 | c.1077del p.E360Kfs*32 | Frame Shift Del (DEL) | VAF 8/56 reads (14%) | called by mutect2, pindel, varscan2
- TAF5L | c.1293_1318del p.C431* | Nonsense Mutation (DEL) | VAF 26/167 reads (16%) | called by mutect2, pindel
- ADAM29 | c.1314T>G p.A438= | Silent (SNP) | VAF 27/72 reads (38%) | catalogued as rs755821340, COSV63662493, COSV63662958; called by muse, mutect2, varscan2
- ADAM7 | c.2043C>T p.V681= | Silent (SNP) | VAF 13/77 reads (17%) | catalogued as rs149009178; called by muse, mutect2
- AGO3 | c.2409A>C p.P803= | Silent (SNP) | VAF 6/50 reads (12%) | catalogued as COSV55792922; called by muse, mutect2
- AGT | c.1329C>A p.T443= | Silent (SNP) | VAF 35/126 reads (28%) | catalogued as COSV64184412, COSV64185414; called by muse, mutect2, varscan2
- AHNAK2 | c.2871C>T p.G957= | Silent (SNP) | VAF 120/227 reads (53%) | catalogued as rs572860937, COSV60913716; called by muse, mutect2, varscan2
- AQP11 | c.642A>C p.V214= | Silent (SNP) | VAF 33/111 reads (30%) | catalogued as COSV57992370; called by muse, mutect2, varscan2
- C9orf135 | c.669T>C p.S223= | Silent (SNP) | VAF 10/57 reads (18%) | catalogued as COSV65875278; called by mutect2, varscan2
- CABP4 | c.690G>A p.E230= | Silent (SNP) | VAF 9/88 reads (10%) | catalogued as COSV57797837, COSV57800232; called by muse, mutect2, varscan2
- CTNND2 | c.1491C>T p.S497= | Silent (SNP) | VAF 42/191 reads (22%) | catalogued as COSV58882979; called by muse, mutect2, varscan2
- DGKB | c.1617C>T p.Y539= | Silent (SNP) | VAF 12/58 reads (21%) | catalogued as rs762809124, COSV51767426; called by muse, mutect2
- DNAH17 | c.12780G>A p.L4260= | Silent (SNP) | VAF 9/81 reads (11%) | catalogued as COSV53144752; called by muse, mutect2, varscan2
- EIF3A | c.2859C>T p.D953= | Silent (SNP) | VAF 72/195 reads (37%) | catalogued as rs148664870; called by muse, mutect2, varscan2
- HEATR4 | c.645C>A p.A215= | Silent (SNP) | VAF 9/38 reads (24%) | catalogued as COSV58571713; called by muse, mutect2, varscan2
- IQGAP2 | c.2991G>A p.S997= | Silent (SNP) | VAF 10/21 reads (48%) | catalogued as rs144328533; called by muse, varscan2
- KIF1A | c.2718G>A p.S906= | Silent (SNP) | VAF 22/46 reads (48%) | catalogued as rs769618125, COSV100240182, COSV57487213; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KLC3 | c.1119C>T p.N373= | Silent (SNP) | VAF 10/47 reads (21%) | catalogued as rs371987569; called by muse, mutect2, varscan2
- LAMA1 | c.1620G>A p.P540= | Silent (SNP) | VAF 28/65 reads (43%) | catalogued as rs765638301, COSV67535741; called by muse, mutect2, varscan2
- MRGPRX4 | c.12C>T p.T4= | Silent (SNP) | VAF 21/149 reads (14%) | catalogued as rs369423824; called by muse, mutect2
- NEURL4 | c.3342C>T p.G1114= | Silent (SNP) | VAF 25/47 reads (53%) | catalogued as COSV59748956; called by muse, mutect2, varscan2
- OR8H3 | c.922A>C p.R308= | Silent (SNP) | VAF 16/60 reads (27%) | catalogued as COSV57908605, COSV57911024, COSV57912112; called by muse, mutect2, varscan2
- PCDH10 | c.1872C>T p.N624= | Silent (SNP) | VAF 29/67 reads (43%) | catalogued as rs540013540, COSV52088507; called by muse, mutect2, varscan2
- PCDHA6 | c.300G>A p.A100= | Silent (SNP) | VAF 62/260 reads (24%) | catalogued as COSV65352163; called by muse, varscan2
- PNPT1 | c.1756T>C p.L586= | Silent (SNP) | VAF 18/46 reads (39%) | catalogued as rs750328203, COSV53176980; ClinVar: likely benign; called by muse, mutect2, varscan2
- RETSAT | c.960G>A p.V320= | Silent (SNP) | VAF 16/95 reads (17%) | catalogued as rs372505970; called by muse, mutect2, varscan2
- SH2D3C | c.2070T>C p.G690= (on ENST00000314830 / NM_170600.3; = p.G533= on NM_005489.4) | Silent (SNP) | VAF 14/82 reads (17%) | catalogued as COSV59121802; called by muse, mutect2, varscan2
- SYNE1 | c.6789A>G p.E2263= (on ENST00000367255 / NM_182961.4; = p.E2270= on NM_033071.3) | Silent (SNP) | VAF 18/66 reads (27%) | catalogued as COSV54962851; called by muse, mutect2, varscan2
- UTP20 | c.6108G>C p.L2036= | Silent (SNP) | VAF 3/20 reads (15%) | catalogued as rs768499716, COSV55375812; called by muse, mutect2
- VPS52 | c.1614G>A p.Q538= | Silent (SNP) | VAF 30/200 reads (15%) | catalogued as COSV71403463; called by muse, mutect2, varscan2
- AC244258.1 | n.265C>A | RNA (SNP) | VAF 9/29 reads (31%) | called by muse, mutect2, varscan2
- CAPRIN2 | c.2148+1586G>T | Intron (SNP) | VAF 22/101 reads (22%) | catalogued as COSV51832114; called by muse, mutect2, varscan2
- CPLANE1 | c.*5873G>T | 3'UTR (SNP) | VAF 24/155 reads (15%) | catalogued as COSV57057988; called by muse, mutect2, varscan2
- DST-AS1 | n.139+7521G>C | Intron (SNP) | VAF 5/37 reads (14%) | catalogued as COSV66094391; called by muse, mutect2, varscan2
